Gene-level copy-number profile of specimen HCM-BROD-0953-C34-85B from HCMI case HCM-BROD-0953-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; Tumor grade: GX; Age at diagnosis: 61.4 years (22,416 days).
Specimen HCM-BROD-0953-C34-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9d377d69-227a-42c3-ac46-be006783f821.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0953-C34-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/156742a8-820a-49c5-9855-516aeeed6ed1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 75; copy number 3: 4,980; copy number 4: 24,401; copy number 5: 9,962; copy number 6: 12,236; copy number 7: 4,885; copy number 8: 435; copy number 9: 357; copy number 10: 33; copy number 11: 16; copy number 12: 1,244; copy number 13: 1; copy number 14: 1; copy number 15: 31; copy number 16: 22; copy number 17: 50; copy number 19: 20; copy number 20: 33; copy number 22: 52; copy number 25: 55; copy number 26: 2; copy number 27: 14.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,931 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:51,886,688–54,310,582, 31 genes, copy number 9–13 (within-gene range 4–13): RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2, B3GNTL1P1, AC022133.1, AC025180.1, ITGA2, AC008966.3, AC008966.2, MOCS2, AC008966.1, AC026477.1, AC108114.1, FST, NDUFS4, LINC02105, ASS1P9, AC025175.1, ARL15, AC025175.2, RNU6-272P, MIR581, RN7SL801P, AC016601.1.
- chr5:54,517,759–56,925,532, 61 genes, copy number 9–19 (within-gene range 7–19) (broad region; genes not listed).
- chr5:59,314,110–60,304,151, 5 genes, copy number 10 (within-gene range 10–11): AC008833.1, NDUFB4P2, MIR582, AC034234.1, RNU6-806P.
- chr5:64,768,930–65,020,989, 3 genes, copy number 10–12: CWC27, AC092354.2, AC092354.1.
- chr6:68,223,667–68,329,899, 2 genes, copy number 9: AL593844.1, LINC02549.
- chr6:68,598,204–69,389,506, 3 genes, copy number 9 (within-gene range 8–9): AL606923.1, AL391807.1, ADGRB3.
- chr6:168,920,394–170,276,762, 29 genes, copy number 9 (within-gene range 7–9): AL513210.1, AL109924.3, AL109924.1, AL109924.2, LINC01615, LINC02544, BX322234.1, THBS2, BX322234.2, VTA1P1, LINC02519, AL031315.1, AL135910.1, WDR27, C6orf120, PHF10, AL354892.2, AL354892.1, TCTE3, ERMARD, AL354892.3, LINC00242, LINC00574, AL049612.1, AL596442.1, AL596442.2, RPL12P23, AL109910.1, AL109910.2.
- chr6:170,290,703–170,407,067, 1 gene, copy number 9 (within-gene range 7–9): FAM120B.
- chr6:170,414,139–170,419,325, 1 gene, copy number 9: AL008628.1.
- chr8:42,416,475–43,363,518, 29 genes, copy number 9–10 (within-gene range 8–10): SLC20A2, AC093367.1, AC090739.1, SMIM19, CHRNB3, AC103843.1, AC103843.2, CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8.
- chr8:63,465,831–145,066,685, 1,243 genes, copy number 9–12 (within-gene range 7–12) (broad region; genes not listed).
- chr9:61,190,003–61,662,690, 11 genes, copy number 9–11: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1.
- chr11:69,147,228–71,818,238, 71 genes, copy number 25–27 (within-gene range 6–27) (broad region; genes not listed).
- chr12:34,149,839–38,274,549, 18 genes, copy number 19–22: AC140847.1, AC140847.3, TUBB8P4, AC140847.2, RNA5SP357, DUX4L27, AK6P1, ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA.
- chr12:38,532,895–47,782,751, 135 genes, copy number 17–22 (within-gene range 5–22) (broad region; genes not listed).
- chr12:83,661,009–96,043,520, 180 genes, copy number 9 (broad region; genes not listed).
- chr12:97,430,884–102,958,410, 104 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr13:114,281,601–114,337,626, 4 genes, copy number 9: UPF3A, CLCP2, CHAMP1, LINC01054.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
